Surgical pathology report (de-identified scan), TCGA case TCGA-E3-A3E2, project TCGA-THCA (Thyroid Carcinoma), tissue source site Roswell Park, specimen TCGA-E3-A3E2-01A (Primary Tumor).

[page 1 of 2]
Surgery Date:

SPECIMENS:

- A. PRE TRACHEAL LYMPH NODE
- B. THYROID WITH PARATRACHEAL NODES
- C. RIGHT PARATRACHEAL NODE

DIAGNOSIS:

- A. LYMPH NODE, PRETRACHEAL BIOPSY:
- ONE BENIGN LYMPH NODE (0/1)
- B. THYROID AND PARATRACHEAL LYMPH NODE, THYROIDECTOMY:
- PAPILLARY CARCINOMA OF THYROID, FOLLICULAR VARIANT (1.0CM)
- TWO OF EIGHT PARATRACHEAL LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/8)
- BENIGN, PARATHYROID
- NEGATIVE RESECTION MARGIN
- CHRONIC LYMPHOCYTIC THYROIDITIS
- C. LYMPH NODE, RIGHT PARATRACHEAL, BIOPSY:
- ONE BENIGN LYMPH NODE (0/1)

1C5-0-3

THYROID TEMPLATE

Specimen Type: Total thyroidectomy
Tumor Site: Right lobe
Tumor Focality: Multifocal
Tumor Size (Largest nodule): 1.0cm
Additional Dimensions: 1.0x0.7cm
Histologic Type: Papillary carcinoma
- Follicular variant
Margins: Margins uninvolved by carcinoma
- Distance of carcinoma to closest margins: <1mm
Venous/Lymphatic Invasion: Absent
Additional Findings: Thyroiditis
Lymph Nodes:
Pathologic Stage: pT 1, N 1a, Mx

carcinoma, papillary, follicular variant
8340/3

Site: Thyroid, NOS C73.9

for 10/26/11

Primary Tumor (pT):
pT1: Tumor size 2cm or less, limited to thyroid

Regional Lymph Nodes (pN):
PN1a: Nodal metastasis to Level VI (pretracheal and prelaryngeal/Delphian) lymph nodes

Distant Metastases(pM):
PMX: Cannot be assessed

SPECIMEN(S):

- A. PRE TRACHEAL LYMPH NODE B. THYROID WITH PARATRACHEAL NODES C. RIGHT PARATRACHEAL NODE

CLINICAL HISTORY:

None given

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSC: Lymph node: Negative for tumor
By Dr., called to Dr. at

[page 2 of 2]
GROSS DESCRIPTION:

A. PRE TRACHEAL LYMPH NODE

Received in formalin and labeled as "pre tracheal lymph node" is a pink-tan lymph node measuring 0.8x0.5x0.3cm. Submitted in toto in block A1.

B. THYROID WITH PARATRACHEAL NODES

Received fresh for tissue procurement and labeled "total thyroid with paratracheal node" is a 15gm thyroid gland with the right lobe measuring 5.0x2.5x0.9cm, isthmus is 1.5x1.2x0.3cm and the left lobe is 4.0x2.5x0.7cm. The serosa is unremarkable. The specimen is inked as follows: posterior-red, anterior left lobe-blue, anterior isthmus-orange, anterior right lobe-black. Specimen is serially sectioned from superior left lobe to inferior and the isthmus from left to right and no abnormalities are seen. The right lobe is sectioned from superior to inferior and there is a well circumscribed, firm, white-tan nodule present measuring 1.0x1.0x0.7cm which is located in the mid portion of the medial side. The remainder of the parenchyma has a meaty red appearance. Specimen is submitted in toto as follows:

B1-B4: left lobe, serially submitted from superior to inferior

B5: isthmus

B6-B12: right lobe, submitted from superior to inferior, mass is submitted in toto in block B10

Representative section is submitted for tissue procurement.

C. RIGHT PARATRACHEAL NODE

Received fresh and labeled as "right paratracheal node" is a 0.7x0.4x0.3cm lymph node. It is submitted in toto for frozen section in block labeled FSC1.

Gross Dictation: , ,

Microscopic/Diagnostic Dictation: , M.D., PATHOLOGIST

Final Review: , M.D., PATHOLOGIST,

Final Review: , M.D., PATHOLOGIST.

Final: , M.D., PATHOLOGIST, (

H.P.A.A. Discrepancy		/

Source: NCI Genomic Data Commons file b14698bd-3ea7-487f-8ff0-15c4316c01db (TCGA-E3-A3E2.8449B3D4-33B2-4C33-8357-FA189B778624.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).